Somatic mutation profile of tumor specimen MP2PRT-PAPNXK-TBP1-A (aliquot MP2PRT-PAPNXK-TBP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPNXK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,219 days).
Specimen MP2PRT-PAPNXK-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7808517-06a1-45c2-acd2-356b1de93807.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPNXK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPNXK-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce26e26e-ec1f-4263-963d-c350cfaab3b5

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs757626981; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1439369979; called by muse, mutect2, varscan2
- FAM47A | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 235/473 reads (50%) | catalogued as COSV60493858, COSV60495686; called by muse, mutect2, varscan2
- FLT3 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- MUC17 | c.9704C>G p.A3235G | Missense Mutation (SNP) | VAF 121/252 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV60285296; called by muse, mutect2, varscan2
- RBMXL2 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 183/383 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs1387848815, COSV60981321; called by muse, mutect2, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- NRSN1 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 57/488 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- VSX2 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 193/626 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBN1 | c.4341T>A p.I1447= | Silent (SNP) | VAF 69/165 reads (42%) | called by muse, mutect2, varscan2
- GJA1 | c.411C>T p.Y137= | Silent (SNP) | VAF 141/477 reads (30%) | catalogued as rs201088822; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA7 | c.1353C>T p.N451= | Silent (SNP) | VAF 178/388 reads (46%) | catalogued as rs781957990, COSV65343883; called by muse, mutect2, varscan2
- WNK1 | c.1119C>A p.T373= | Silent (SNP) | VAF 103/232 reads (44%) | called by muse, mutect2, varscan2
